Somatic mutation profile of tumor specimen 0DQQBZ from CCDI case PBCFLF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 8.7 years (3,160 days).
Specimen 0DQQBZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 796c1299-b5c8-434b-a1d4-724fee08e800.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQQCW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/877f9d97-3cc4-4cd2-b449-6c1fea7a6db4

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 2, Frame Shift Del 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALD1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 422/1016 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772919992, COSV62653861; called by muse, mutect2, varscan2
- CNGA2 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 376/933 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs561786347, COSV61705080; called by muse, mutect2, varscan2
- DNAH14 | c.4885C>T p.R1629* (on ENST00000445597; = p.R2034* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 169/843 reads (20%) | catalogued as rs1394394477, COSV70540262; called by muse, mutect2, varscan2
- LRP1 | c.11335G>A p.D3779N | Missense Mutation (SNP) | VAF 486/1083 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs755974434, COSV99676923; called by muse, mutect2, varscan2
- PBRM1 | c.4036del p.Q1346Rfs*38 | Frame Shift Del (DEL) | VAF 309/524 reads (59%) | catalogued as COSV56270012; called by mutect2, pindel, varscan2
- SVEP1 | c.8609G>A p.S2870N | Missense Mutation (SNP) | VAF 247/340 reads (73%) | SIFT tolerated (0.51); PolyPhen benign (0.316); catalogued as COSV52835327; called by muse, mutect2, varscan2
- TNFRSF11A | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 375/961 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763222674; called by muse, mutect2, varscan2
- TSTD1 | c.310G>A p.A104T (on ENST00000423014 / NM_001113207.2; = p.A63T on NM_001113206.2) | Missense Mutation (SNP) | VAF 80/1444 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV57039025; called by muse, mutect2
- FAM50B | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 199/847 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- GABRQ | c.1391A>G p.Y464C | Missense Mutation (SNP) | VAF 132/1434 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- NLGN3 | c.727G>A p.G243S (on ENST00000358741 / NM_181303.2; = p.G223S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 329/719 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- NRP2 | c.1942T>A p.F648I | Missense Mutation (SNP) | VAF 84/898 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- SEC14L4 | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 219/589 reads (37%) | called by muse, mutect2, varscan2
- LONP1 | c.786C>A p.P262= | Silent (SNP) | VAF 243/612 reads (40%) | called by muse, mutect2, varscan2
- DMD | c.*81G>T | 3'UTR (SNP) | VAF 35/871 reads (4%) | called by muse, mutect2
